Gene-level copy-number profile of tumor specimen ALCH-B2RV-TTP1-A from ALCHEMIST case ALCH-B2RV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.0 years (22,271 days).
Specimen ALCH-B2RV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 775976e9-6a51-4046-adac-ec3ac877b551.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2RV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/c7b95e4f-9073-468c-b855-0868a3362a1a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 1,437; copy number 2: 56,038; copy number 3: 706; copy number 4: 78; copy number 5: 44; copy number 6: 5; copy number 7: 5; copy number 9: 1; copy number 10: 1; copy number 12: 2; copy number 13: 5; copy number 14: 7; copy number 16: 1; copy number 18: 2; copy number 21: 1; copy number 26: 3; copy number 32: 4; copy number 33: 2; copy number 37: 1; copy number 40: 2; copy number 42: 1; copy number 52: 2.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:944,203–1,000,172, 6 genes (within-gene range 0–1): NOC2L, KLHL17, PLEKHN1, PERM1, AL645608.7, HES4.
- chr8:23,702,451–23,706,598, 1 gene: NKX2-6.
- chr11:1,389,899–1,462,689, 1 gene: BRSK2.
- chr12:111,339,527–111,369,121, 2 genes (within-gene range 0–2): RNA5SP373, PHETA1.
- chr14:18,418,775–18,419,273, 1 gene: BNIP3P6.
- chr14:103,094,723–103,137,439, 4 genes: AL161669.1, EXOC3L4, LINC00677, TNFAIP2.
- chr15:25,172,635–25,215,622, 24 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25.
- chr15:64,739,891–64,775,589, 2 genes: RBPMS2, MIR1272.
- chr15:90,839,641–90,895,776, 4 genes: AC124248.1, RN7SL363P, FURIN, FES.
- chr22:49,572,264–49,575,426, 1 gene (within-gene range 0–2): Z97192.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 89 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:181,699,608–181,699,883, 1 gene, copy number 21 (within-gene range 2–21): AC117415.1.
- chr3:181,847,526–182,142,137, 5 genes, copy number 9–26: AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.1.
- chr3:182,446,970–182,985,953, 14 genes, copy number 12–42: LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1.
- chr3:183,122,215–183,428,778, 4 genes, copy number 10–14: LAMP3, MCF2L2, B3GNT5, RNA5SP151.
- chr3:183,487,551–183,884,933, 9 genes, copy number 16–52 (within-gene range 4–52): KLHL6, KLHL6-AS1, AC068769.1, KLHL24, YEATS2, YEATS2-AS1, AC131160.1, MAP6D1, PARL.
- chr3:183,895,900–184,017,939, 2 genes, copy number 33 (within-gene range 2–33): CYP2AB1P, ABCC5.
- chr9:12,134–118,204, 10 genes, copy number 5: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4.
- chr9:3,218,297–3,526,004, 2 genes, copy number 6 (within-gene range 4–6): RFX3, AL354941.1.
- chr9:4,984,390–5,629,748, 26 genes, copy number 5–7 (within-gene range 4–7): JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2.
- chr9:5,855,781–6,197,248, 7 genes, copy number 5: AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1, GTF3AP1.
- chr9:7,597,823–7,888,380, 3 genes, copy number 5: PPIAP33, AL354694.1, DMAC1.
- chr9:19,108,375–19,149,290, 1 gene, copy number 5: PLIN2.
- chr9:22,446,824–22,455,740, 1 gene, copy number 6: DMRTA1.
- chr9:24,542,952–24,592,104, 2 genes, copy number 6: IZUMO3, AL353811.1.
- chr20:62,877,738–62,937,952, 2 genes, copy number 5: DIDO1, AL117379.1.

Autosomal genes at a single copy (total copy number 1): 1,437. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
